Somatic mutation profile of tumor specimen ASCProject_0221_T2_WES (aliquot ASCProject_0221_T2_WES_1) from CMI case ASCProject_0221, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: female; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 27.1 years (9,905 days).
Specimen ASCProject_0221_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 191a99f0-6b98-4c0c-8621-0e128b77a70e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0221_SALIVA (Saliva), aliquot ASCProject_0221_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02909bb0-7a2c-4450-af4e-f5c3c4d9d827

The open-access MAF lists 38 somatic variants for this specimen: 29 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 5, Frame Shift Del 4, RNA 2, 3'UTR 1, Frame Shift Ins 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.3362C>T p.S1121L | Missense Mutation (SNP) | VAF 61/250 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs63750987, CM014488, CM053089; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3129G>A p.M1043I | Missense Mutation (SNP) | VAF 22/212 reads (10%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs121913283, CM126698, COSV55873376, COSV55878974, COSV55898229; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ABCA3 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 29/256 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.21); catalogued as rs746682954; called by muse, mutect2, varscan2
- ART5 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as rs200339999; called by muse, mutect2, varscan2
- AVPR1A | c.25G>T p.A9S | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV54546071; called by muse, mutect2
- BOK | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs748812814; called by muse, mutect2, varscan2
- CUL7 | c.2317C>T p.R773W | Missense Mutation (SNP) | VAF 34/570 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs1358890131, COSV99538432; called by muse, mutect2
- EPDR1 | c.442G>A p.V148I | Missense Mutation (SNP) | VAF 99/315 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.357); catalogued as rs369217258; called by muse, mutect2, varscan2
- FGF21 | c.392del p.G131Dfs*64 | Frame Shift Del (DEL) | VAF 14/57 reads (25%) | catalogued as COSV55809865; called by mutect2, pindel, varscan2
- FNTA | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 54/358 reads (15%) | catalogued as rs767603793, COSV56491327; called by muse, mutect2, varscan2
- HSPG2 | c.1522G>A p.G508S | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs768887883; called by muse, mutect2, varscan2
- SRGAP2 | c.1210del p.E404Rfs*27 (on ENST00000624873 / NM_001170637.4; = p.E405Rfs*27 on NM_015326.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 66/648 reads (10%) | catalogued as COSV99832810; called by mutect2, pindel
- TMEM132C | c.2714G>C p.G905A | Missense Mutation (SNP) | VAF 9/142 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.228); catalogued as rs866881036; called by muse, mutect2
- UGT3A2 | c.452del p.P151Lfs*3 | Frame Shift Del (DEL) | VAF 57/284 reads (20%) | catalogued as COSV56928229; called by mutect2, pindel, varscan2
- ADAMTS2 | c.3016G>T p.D1006Y | Missense Mutation (SNP) | VAF 39/248 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ARID1A | c.5418del p.S1807Vfs*8 | Frame Shift Del (DEL) | VAF 52/297 reads (18%) | called by mutect2, pindel, varscan2
- ATP2B3 | c.298C>A p.Q100K | Missense Mutation (SNP) | VAF 58/279 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- DIAPH2 | c.3187C>G p.L1063V | Missense Mutation (SNP) | VAF 24/372 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- EPHB4 | c.2400dup p.S801Qfs*2 | Frame Shift Ins (INS) | VAF 43/150 reads (29%) | called by mutect2, pindel, varscan2
- FBN3 | c.5719G>T p.A1907S | Missense Mutation (SNP) | VAF 22/300 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.415); called by muse, mutect2
- GRAP | c.461T>G p.L154W | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.267); called by muse, mutect2
- LRP2 | c.1564G>A p.G522S | Missense Mutation (SNP) | VAF 104/420 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRAS | c.349A>C p.K117Q | Missense Mutation (SNP) | VAF 114/508 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- PIK3CA | c.2869A>C p.T957P | Missense Mutation (SNP) | VAF 26/242 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.656); called by muse, mutect2
- POT1 | c.221A>T p.K74I | Missense Mutation (SNP) | VAF 84/216 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PTPRB | c.5609A>G p.D1870G | Missense Mutation (SNP) | VAF 33/465 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TENM1 | c.369G>A p.M123I | Missense Mutation (SNP) | VAF 117/534 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- TMX4 | c.668C>A p.S223Y | Missense Mutation (SNP) | VAF 73/326 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- ZBTB18 | c.143A>G p.Y48C | Missense Mutation (SNP) | VAF 43/431 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- AHNAK2 | c.11886G>T p.T3962= | Silent (SNP) | VAF 36/378 reads (10%) | catalogued as rs371817706, COSV60908996; called by muse, mutect2
- DOCK11 | c.2946T>A p.I982= | Silent (SNP) | VAF 18/258 reads (7%) | called by muse, mutect2
- ISLR | c.223C>T p.L75= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as COSV99997428; called by muse, mutect2, varscan2
- MECOM | c.738G>C p.A246= (on ENST00000468789 / NM_001105078.4; = p.A434= on NM_004991.4) | Silent (SNP) | VAF 107/344 reads (31%) | catalogued as COSV52960807; called by muse, mutect2, varscan2
- TARM1 | c.261G>A p.A87= (on ENST00000616041 / NM_001330650.1; = p.A79= on NM_001135686.3) | Silent (SNP) | VAF 76/341 reads (22%) | catalogued as rs760187546; called by muse, mutect2, varscan2
- CLCN5 | c.17-32580A>G | Intron (SNP) | VAF 17/389 reads (4%) | catalogued as COSV65800873; called by muse, mutect2
- HAVCR1 | c.*28C>T | 3'UTR (SNP) | VAF 87/475 reads (18%) | catalogued as rs1177354352, COSV100208308; called by muse, mutect2, varscan2
- LINC01193 | n.780T>C | RNA (SNP) | VAF 68/746 reads (9%) | called by muse, mutect2
- MIR125B1 | n.84G>C | RNA (SNP) | VAF 43/182 reads (24%) | called by muse, mutect2, varscan2
